Somatic mutation profile of tumor specimen TCGA-AA-3692-01A (aliquot TCGA-AA-3692-01A-01W-0900-09) from TCGA case TCGA-AA-3692, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 47.0 years (17,167 days).
Specimen TCGA-AA-3692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b2ab9fc-cb6b-4bac-98eb-cfb7835c5b93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3692-10A (Blood Derived Normal), aliquot TCGA-AA-3692-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04b3a01b-7a45-4cd4-8241-8f8d23407498

The open-access MAF lists 68 somatic variants for this specimen: 55 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 53/136 reads (39%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 42/64 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACKR3 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs200095631, COSV56021232; called by muse, mutect2, varscan2
- ACTN2 | c.2465C>T p.T822M | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV63973021; called by muse, mutect2, varscan2
- APC | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 73/178 reads (41%) | catalogued as COSV57322620, COSV57331090; called by muse, mutect2, varscan2
- BTBD7 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs546190692, COSV100597978; called by muse, mutect2
- C1orf94 | c.1234C>T p.R412* (on ENST00000488417 / NM_001134734.2; = p.R222* on NM_032884.5) | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as rs775448857, COSV64914334; called by muse, mutect2, varscan2
- CALCOCO2 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV51954058; called by muse, mutect2, varscan2
- CHUK | c.201-1G>A p.X67_splice | Splice Site (SNP) | VAF 73/104 reads (70%) | catalogued as COSV64917663, COSV64918404; called by muse, mutect2, varscan2
- CLEC4D | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV55231282; called by muse, mutect2, varscan2
- CR1 | c.4175G>A p.R1392H | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.738); catalogued as rs200621891, COSV65462323; called by muse, mutect2, varscan2
- CREB3L4 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as rs777111235, COSV55133305; called by muse, mutect2, varscan2
- CSMD3 | c.4678C>A p.L1560I (on ENST00000297405 / NM_001363185.1; = p.L1456I on NM_052900.3) | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV52228120, COSV52350352; called by muse, mutect2, varscan2
- CXorf65 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs180690065, COSV52150533; called by muse, mutect2, varscan2
- DIAPH2 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV61296854; called by muse, mutect2, varscan2
- DNTTIP2 | c.520C>G p.P174A | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV63284790; called by muse, mutect2, varscan2
- DOCK2 | c.4994+1G>C p.X1665_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99913545; called by muse, mutect2, varscan2
- DPP3 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766673185, COSV64758348; called by muse, mutect2
- DYNC2H1 | c.9065G>A p.R3022K | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV62109731; called by muse, mutect2, varscan2
- FOXP2 | c.1266+1G>A p.X422_splice | Splice Site (SNP) | VAF 51/127 reads (40%) | catalogued as COSV63495546; called by muse, mutect2, varscan2
- GJB7 | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738461; called by muse, mutect2
- GPR37 | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100390992, COSV58255171; called by muse, mutect2
- GRK5 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs556570876, COSV64868220; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2092C>T p.R698W (on ENST00000265755 / NM_016328.3; = p.R683W on NM_005685.4) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1554357499, COSV56092979; called by muse, mutect2, varscan2
- HTR1A | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60500321; called by muse, mutect2
- INO80 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs572481309, COSV62737367; called by muse, mutect2, varscan2
- IQCA1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200287685, COSV54498476, COSV54515162; called by muse, mutect2, varscan2
- IRAG1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368966460, COSV70211482; called by muse, mutect2, varscan2
- KLHL18 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV51749200; called by muse, mutect2, varscan2
- KRR1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1181050757, COSV56992154; called by muse, mutect2
- METTL1 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99141596; called by muse, mutect2, varscan2
- OR2M2 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 236/649 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62899641; called by muse, mutect2, varscan2
- P2RY4 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs775969220, COSV65736719; called by muse, mutect2, varscan2
- P2RY4 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.267); catalogued as COSV65737166; called by muse, mutect2, varscan2
- PAPPA2 | c.1376G>T p.S459I | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV62788663; called by muse, mutect2, varscan2
- PCDHGA10 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.484); catalogued as rs1369274783, COSV54055371; called by muse, mutect2, varscan2
- PGGT1B | c.608G>C p.S203T | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56975861; called by muse, mutect2, varscan2
- PIP5K1A | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.077); catalogued as COSV62958485, COSV62960486; called by muse, mutect2, varscan2
- PTEN | c.375del p.A126Lfs*8 | Frame Shift Del (DEL) | VAF 69/132 reads (52%) | catalogued as COSV64292010, COSV64310749; called by mutect2, pindel, varscan2
- PTPRT | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 137/269 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV62032295; called by muse, mutect2, varscan2
- RAPGEF5 | c.955T>G p.F319V | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs1288009261, COSV59793982; called by muse, mutect2, varscan2
- RMDN3 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as rs201035155, COSV53025895; called by muse, mutect2, varscan2
- SLC4A8 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 156/400 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs578147476, COSV60653980; called by muse, mutect2, varscan2
- SLITRK4 | c.1618G>T p.V540L | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV62026650; called by muse, mutect2, varscan2
- SNAPC1 | c.200dup p.L67Ffs*21 | Frame Shift Ins (INS) | VAF 22/57 reads (39%) | catalogued as rs753183177; called by mutect2, pindel, varscan2
- TAF1L | c.2738C>A p.A913E | Missense Mutation (SNP) | VAF 154/321 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54271622; called by muse, mutect2, varscan2
- TAF4 | c.2995A>G p.M999V | Missense Mutation (SNP) | VAF 104/167 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV53344290; called by muse, mutect2, varscan2
- THRB | c.497T>A p.F166Y | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as COSV54982919; called by muse, mutect2, varscan2
- TUBG2 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.355); catalogued as rs753214599, COSV52220011; called by muse, mutect2, varscan2
- USP28 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.848); catalogued as COSV50204105; called by muse, mutect2, varscan2
- WDR3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.266); catalogued as rs139865932; called by muse, mutect2, varscan2
- YLPM1 | c.5426G>T p.R1809L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV53122763; called by muse, mutect2
- ZNF235 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV52158864; called by muse, mutect2, varscan2
- RPL10A | c.404del p.P135Lfs*17 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | called by mutect2, pindel, varscan2
- TRIM25 | c.462_463insTTTGCGC p.R155Ffs*32 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ERVW-1 | c.1233C>T p.S411= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs745829714, COSV101423849; called by muse, mutect2, varscan2
- GRINA | c.930C>T p.I310= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs782480856, COSV57593866; called by muse, mutect2, varscan2
- HEPACAM2 | c.387T>C p.N129= (on ENST00000394468 / NM_001039372.4; = p.N117= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as rs1438617679, COSV59064126; called by muse, mutect2, varscan2
- IL21R | c.1479C>A p.G493= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV61973185; called by mutect2, varscan2
- INHBA | c.753C>T p.G251= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs776081862, COSV54224528; called by muse, mutect2, varscan2
- LAPTM4B | c.846C>G p.V282= (on ENST00000445593; = p.V191= on NM_018407.6) | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as COSV71454072, COSV71455023; called by muse, mutect2, varscan2
- LSM4 | c.93C>T p.S31= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV53254295; called by muse, mutect2, varscan2
- MAP2 | c.5160C>T p.G1720= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs780072425, COSV52312223; called by muse, mutect2, varscan2
- PCDH17 | c.723G>A p.P241= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV64980703; called by muse, mutect2, varscan2
- SYNGAP1 | c.1752C>T p.I584= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV53387541; called by muse, mutect2, varscan2
- TRIM10 | c.42C>A p.V14= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV64990692; called by muse, mutect2
- H2BP2 | chr1:143874808 A>G | 3'Flank (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- MIR508 | n.97C>T | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as rs369217552; called by muse, mutect2, varscan2
